Somatic mutation profile of tumor specimen TARGET-20-PARGVC-03A (aliquot TARGET-20-PARGVC-03A-01D) from TARGET case TARGET-20-PARGVC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,802 days).
Specimen TARGET-20-PARGVC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2a0aefa-da40-4325-9618-24f879f90c71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGVC-14A (Bone Marrow Normal), aliquot TARGET-20-PARGVC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acbe388-6710-4324-b75f-c5f0463eb068

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 132/313 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DAG1 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58185767; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2
- KIAA1109 | c.13127G>A p.R4376K | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV52696181, COSV52697969; called by muse, mutect2, varscan2
- LIG3 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 128/282 reads (45%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV52009256; called by muse, mutect2, varscan2
- ME1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 228/498 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs752555482, COSV63843067; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 190/387 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2, varscan2
- TRABD2A | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372215440; called by muse, mutect2, varscan2
- TRERF1 | c.1140_1141insCTCC p.E381Lfs*24 | Frame Shift Ins (INS) | VAF 35/98 reads (36%) | catalogued as COSV61674938; called by mutect2, pindel, varscan2
- UBE4B | c.3571C>T p.R1191W (on ENST00000343090 / NM_001105562.3; = p.R1062W on NM_006048.5) | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1419508654, COSV53536654; called by muse, mutect2, varscan2
- ACTB | c.329_331dup p.L110_N111insM | In Frame Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R15A | c.1992G>A p.A664= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as rs186438232; called by muse, mutect2, varscan2
- SRP72 | c.1732C>T p.L578= | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as COSV61378483; called by muse, mutect2, varscan2
